CCDI case PBCBTB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e21a1ff7-754f-4b89-9a93-2d6c36f80ad6

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Atypical choroid plexus papilloma: ICD-O-3 morphology code: 9390/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 1.7 years (621 days).

Biospecimens (3 samples)
- Sample 0DNJA7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJBL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
